Somatic mutation profile of tumor specimen TCGA-2Y-A9HB-01A (aliquot TCGA-2Y-A9HB-01A-11D-A38X-10) from TCGA case TCGA-2Y-A9HB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.7 years (24,359 days).
Specimen TCGA-2Y-A9HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8ab635e-a902-4995-8f2a-e744c3959046.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9HB-10A (Blood Derived Normal), aliquot TCGA-2Y-A9HB-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f96a4d28-f807-482a-bdfa-af00a98b10fd

The open-access MAF lists 81 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 27/127 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55970780, COSV99718649; called by muse, mutect2, varscan2
- ANK2 | c.6930G>T p.E2310D | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV100002356; called by muse, mutect2, varscan2
- APC | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99968495; called by muse, mutect2, varscan2
- BIRC6 | c.13792T>G p.F4598V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV101428410; called by muse, mutect2
- BTNL9 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs755536857, COSV100576173, COSV59797640; called by muse, mutect2, varscan2
- DLK1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as COSV100375283; called by muse, mutect2, varscan2
- DOCK7 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.412); catalogued as rs1557822340, COSV99224901; called by muse, mutect2, varscan2
- EGR4 | c.509G>C p.C170S (on ENST00000545030; = p.C67S on NM_001965.4) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV101474255; called by muse, mutect2, varscan2
- EIF4A2 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99961255; called by muse, mutect2, varscan2
- EPPK1 | c.6743C>A p.A2248D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101599878; called by muse, mutect2
- FAM160A2 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99792184; called by muse, mutect2, varscan2
- FAM20B | c.1012A>T p.T338S | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99762428; called by muse, mutect2, varscan2
- FANCE | c.1520C>G p.T507S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100003395; called by muse, mutect2, varscan2
- GRK4 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100584105; called by muse, mutect2
- HECTD1 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101237418; called by muse, mutect2
- IFNA8 | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs749813454, COSV101206913; called by muse, mutect2, varscan2
- KMT5B | c.1166dup p.N389Kfs*6 (on ENST00000304363 / NM_001300907.1; = p.N389Kfs*5 on NM_016028.4) | Frame Shift Ins (INS) | VAF 22/67 reads (33%) | catalogued as rs1434065199; called by mutect2, varscan2
- LARS2 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV99647934; called by muse, mutect2, varscan2
- LRP2 | c.3637T>G p.C1213G | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789082; called by muse, mutect2, varscan2
- MATK | c.1360C>A p.H454N (on ENST00000310132 / NM_139355.3; = p.H455N on NM_002378.4) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV100036149; called by muse, mutect2, varscan2
- MEGF10 | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV57248963; called by muse, mutect2, varscan2
- NDRG2 | c.280A>C p.N94H (on ENST00000298687 / NM_001354570.1; = p.N80H on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV100069048; called by muse, mutect2, varscan2
- NFIC | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59413275; called by muse, mutect2, varscan2
- NLGN4X | c.2190G>T p.M730I | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.062); catalogued as rs770882050, COSV99322421, COSV99323025; called by muse, mutect2, varscan2
- NR0B1 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.885); catalogued as COSV100973544; called by muse, mutect2, varscan2
- NR2F2 | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67683079, COSV67684038; called by muse, mutect2
- NTRK3 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100446993; called by muse, mutect2, varscan2
- OR1J1 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99403175; called by muse, mutect2, varscan2
- OR51B2 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766504415, COSV100173408; called by muse, mutect2, varscan2
- PDPR | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as COSV99848469; called by muse, mutect2, varscan2
- PDXP | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV99312897; called by muse, mutect2, varscan2
- PGBD5 | c.214C>T p.Q72* (on ENST00000525115; = p.Q141* on NM_001258311.2) | Nonsense Mutation (SNP) | VAF 87/142 reads (61%) | catalogued as COSV100358663; called by muse, mutect2, varscan2
- PITX3 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.189); catalogued as COSV100892811; called by muse, mutect2, varscan2
- PTCH2 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs368630408; called by muse, mutect2, varscan2
- PXDNL | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs766523476, COSV62485333, COSV62485839; called by muse, mutect2, varscan2
- RAD50 | c.2332A>G p.I778V | Missense Mutation (SNP) | VAF 88/314 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1554099107, COSV99529132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV3L | c.3650A>C p.K1217T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100725318; called by muse, mutect2
- RNF40 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100222169; called by muse, mutect2, varscan2
- RPS6KA3 | c.627A>T p.L209F | Missense Mutation (SNP) | VAF 168/367 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101084464; called by muse, mutect2, varscan2
- RTCA | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as COSV99559932; called by muse, mutect2, varscan2
- RYR2 | c.8344A>G p.M2782V | Missense Mutation (SNP) | VAF 231/407 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1425494520, COSV100771211; called by muse, mutect2, varscan2
- SAPCD2 | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV101294043; called by muse, mutect2, varscan2
- SEMA6D | c.1472A>T p.Q491L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100317179; called by muse, mutect2
- SERPINA1 | c.611_612del p.T204Sfs*11 | Frame Shift Del (DEL) | VAF 40/127 reads (31%) | catalogued as rs921982028; called by pindel, varscan2
- SERPINE2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs769734047, COSV99296807; called by muse, mutect2, varscan2
- SLC4A2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100055515; called by muse, mutect2, varscan2
- SMG7 | c.2987A>G p.H996R | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100750400; called by muse, mutect2, varscan2
- SNX17 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV52010218; called by muse, mutect2, varscan2
- SOS2 | c.850T>A p.L284M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.486); catalogued as COSV99366317; called by muse, mutect2, varscan2
- STAG2 | c.1731+1G>C p.X577_splice | Splice Site (SNP) | VAF 96/154 reads (62%) | catalogued as COSV99494012; called by muse, mutect2, varscan2
- STAT5A | c.1049C>G p.A350G | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV100604640; called by muse, mutect2, varscan2
- TG | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as COSV55066727, COSV99601574; called by muse, mutect2, varscan2
- TMEM207 | c.55T>G p.L19V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV100719003; called by muse, mutect2
- TNFRSF10B | c.749-1G>A p.X250_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV99375439; called by muse, mutect2, varscan2
- YBX3 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747930990, COSV99685202; called by muse, mutect2, varscan2
- ZNF644 | c.907T>C p.Y303H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); catalogued as COSV100494545; called by muse, mutect2, varscan2
- GRIK2 | c.839del p.R280Kfs*3 | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | called by mutect2, pindel, varscan2
- SIGLEC15 | c.648_650del p.E216_G217delinsD | In Frame Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- AARD | c.168G>A p.L56= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV100991912, COSV65600019; called by muse, mutect2, varscan2
- AGAP2 | c.3327G>A p.L1109= (on ENST00000547588 / NM_001122772.2; = p.L753= on NM_014770.4) | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs1402533600, COSV99223545; called by muse, mutect2, varscan2
- ARHGEF10L | c.3102C>G p.T1034= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99393147; called by muse, mutect2, varscan2
- CAMSAP1 | c.1566G>A p.T522= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs763674817, COSV56722046; called by muse, mutect2, varscan2
- DOCK7 | c.2541A>G p.S847= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs1473915394, COSV99224899; called by muse, mutect2, varscan2
- EVC2 | c.2580T>C p.A860= | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as COSV100186241; called by muse, mutect2
- FASN | c.5307T>C p.I1769= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV100147956; called by muse, mutect2, varscan2
- FAT3 | c.7506A>T p.V2502= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV99967317; called by muse, mutect2, varscan2
- JAKMIP1 | c.450G>A p.R150= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99289924; called by muse, mutect2, varscan2
- JPH1 | c.1647G>A p.Q549= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100646659; called by muse, mutect2, varscan2
- MEMO1 | c.150A>G p.A50= | Silent (SNP) | VAF 133/350 reads (38%) | catalogued as COSV99704333; called by muse, mutect2, varscan2
- MIS18A | c.645A>G p.L215= | Silent (SNP) | VAF 114/228 reads (50%) | catalogued as rs1180716137, COSV99267069; called by muse, mutect2, varscan2
- OSBPL3 | c.111G>A p.V37= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV100514254; called by muse, mutect2, varscan2
- PLXNB3 | c.5448C>A p.I1816= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100737563; called by muse, mutect2
- RNF150 | c.312C>A p.P104= | Silent (SNP) | VAF 44/173 reads (25%) | catalogued as COSV100153705; called by muse, mutect2, varscan2
- SORL1 | c.1461C>T p.L487= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99494294; called by muse, mutect2, varscan2
- TDP1 | c.828G>T p.R276= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV59643201; called by muse, mutect2, varscan2
- TNRC6A | c.4797G>A p.S1599= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs773542201, COSV59362011; called by muse, mutect2, varscan2
- TOP1MT | c.699G>T p.A233= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100239488, COSV100239837; called by muse, mutect2
- TOP2A | c.786G>A p.L262= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV101396241; called by muse, mutect2
- WDR64 | c.999T>G p.V333= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV100843824; called by muse, mutect2, varscan2
- MCRS1 | c.11-181G>C | Intron (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100657379; called by muse, mutect2, varscan2
